Gene-level copy-number profile of tumor specimen HCM-CSHL-0384-D37-31B from HCMI case HCM-CSHL-0384-D37, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 51.4 years (18,759 days).
Specimen HCM-CSHL-0384-D37-31B: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e821fd19-3ad3-4004-927b-9f7efba38cc9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0384-D37-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/82b50c01-a33f-4cb9-b552-980cda736904

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 6,646; copy number 2: 52,102; copy number 3: 130; copy number 4: 12; copy number 5: 5; copy number 6: 7; copy number 10: 2.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr9:136,249,978–136,251,205, 1 gene: CR392000.1.
- chr9:136,992,422–136,996,568, 2 genes: PAXX, CLIC3.
- chr16:89,818,179–89,871,319, 1 gene: SPIRE2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,196,250–136,205,128, 1 gene, copy number 6: LHX3.
- chr9:136,327,476–136,363,744, 2 genes, copy number 6–10 (within-gene range 4–10): GPSM1, DNLZ.
- chr9:136,975,092–136,986,410, 3 genes, copy number 6 (within-gene range 3–6): PTGDS, AL807752.7, LCNL1.
- chr9:137,220,247–137,229,640, 3 genes, copy number 6–10: RNF208, CYSRT1, RNF224.
- chr9:137,277,726–137,302,271, 5 genes, copy number 5: TOR4A, BX255925.2, BX255925.1, BX255925.4, NRARP.

Autosomal genes at a single copy (total copy number 1): 3,790. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
